Somatic mutation profile of tumor specimen HCM-CSHL-0373-C25-01A (aliquot HCM-CSHL-0373-C25-01A-21D-A79M-36) from HCMI case HCM-CSHL-0373-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,274 days).
Specimen HCM-CSHL-0373-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f418d359-79c7-4176-b85b-b54f92668f4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0373-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0373-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f0bd04f-49e3-46aa-9b67-9384209a7587

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 63/376 reads (17%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 84/267 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PYGL | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113993986, CM078414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 161/407 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARID1A | c.6526C>T p.Q2176* | Nonsense Mutation (SNP) | VAF 117/370 reads (32%) | catalogued as COSV61384821; called by muse, mutect2, varscan2
- BCAR1 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 257/821 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754367401; called by muse, mutect2, varscan2
- CASP2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs775676786, COSV100131025; called by muse, mutect2, varscan2
- CD1D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777157013, COSV63808414; called by muse, mutect2, varscan2
- CTNND2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 126/622 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs201021638, COSV58918848; called by muse, mutect2, varscan2
- DDX50 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV101007301; called by muse, mutect2, varscan2
- FAT3 | c.12542G>A p.R4181H | Missense Mutation (SNP) | VAF 141/487 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs368233172, COSV53170350; called by muse, mutect2, varscan2
- NLRP5 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs749175273, COSV66762758; called by muse, mutect2, varscan2
- OR2T3 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 48/442 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs530686348, COSV100613049; called by muse, mutect2
- PBRM1 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as COSV56260223, COSV56261335; called by muse, mutect2, varscan2
- PDE3A | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 291/988 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.898); catalogued as COSV62973060; called by muse, mutect2, varscan2
- PLEKHG3 | c.460C>T p.R154W (on ENST00000394691; = p.R210W on NM_001308147.2) | Missense Mutation (SNP) | VAF 203/547 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs769014906; called by muse, mutect2, varscan2
- SLC12A9 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 213/752 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs765600074; called by muse, mutect2, varscan2
- UNC5A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 129/542 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768440834; called by muse, mutect2, varscan2
- USP6NL | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 135/643 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767258666; called by muse, mutect2, varscan2
- ATOH1 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 274/952 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- BMI1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); called by mutect2, varscan2
- DHX34 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GAD2 | c.975+1_975+3del p.X325_splice | Splice Site (DEL) | VAF 23/159 reads (14%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 94/904 reads (10%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1829C>A p.T610N | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAGEL2 | c.867T>G p.I289M | Missense Mutation (SNP) | VAF 129/546 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP7 | c.2092C>T p.H698Y (on ENST00000340844 / NM_206828.3; = p.H670Y on NM_139176.3) | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.358); called by mutect2, varscan2
- PCDHGA4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDZD2 | c.5421dup p.H1808Tfs*2 | Frame Shift Ins (INS) | VAF 44/244 reads (18%) | called by mutect2, pindel, varscan2
- RANBP3L | c.831A>C p.Q277H | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RPRM | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 164/523 reads (31%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF1 | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ADAMTS18 | c.3648A>G p.S1216= | Silent (SNP) | VAF 50/182 reads (27%) | called by mutect2, varscan2
- BTN1A1 | c.687G>A p.K229= | Silent (SNP) | VAF 76/197 reads (39%) | catalogued as rs201998297, COSV55070254; called by muse, mutect2, varscan2
- CDH26 | c.1260C>T p.A420= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs1316778719; called by muse, mutect2, varscan2
- ISX | c.525G>A p.L175= | Silent (SNP) | VAF 87/501 reads (17%) | called by muse, mutect2, varscan2
- SARAF | c.120G>A p.R40= | Silent (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- TRIM27 | c.303G>A p.E101= | Silent (SNP) | VAF 364/964 reads (38%) | catalogued as rs757487790; called by muse, mutect2, varscan2
- TUBGCP6 | c.2988C>A p.G996= | Silent (SNP) | VAF 123/560 reads (22%) | called by muse, mutect2, varscan2
- USP31 | c.459C>G p.A153= | Silent (SNP) | VAF 164/812 reads (20%) | catalogued as COSV54850884, COSV54852733; called by muse, mutect2, varscan2
- XKR7 | c.1566C>A p.V522= | Silent (SNP) | VAF 178/555 reads (32%) | called by muse, varscan2
- CYGB | c.*176G>T | 3'UTR (SNP) | VAF 190/590 reads (32%) | called by muse, mutect2, varscan2
- MCTP1 | c.721-63984del | Intron (DEL) | VAF 44/291 reads (15%) | called by mutect2, pindel, varscan2
- SPAG11B | c.*141A>G | 3'UTR (SNP) | VAF 34/565 reads (6%) | called by muse, mutect2
